Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1Z4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1Z4-06A (Metastatic).

Prof. Dr. [redacted]

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, NOS C77.9

for 7/24/11

Patient: XXXX
geb. *** **

Datum:

Translation of pathology report

Sample

Gross Pathology

Cryofixated specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 85 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. Some apoptotic cells are present. There is a high nucleo/cytoplasmatic ratio. The mitotic count is 12 mitoses per square millimetre. The tumor cells have a middle sized eosinophilic cytoplasm. The tumor shows a sheet and nest like growth pattern. Lymphocytic infiltrates compound approx. 10 percent of the tissue cells. The tumor harbours approx. 20 percent of necrotic tissue.

Diagnosis: Parts of a malignat tumor, consistent with a metastasis of a melanoma.

Di

CGCF Site = Regional lymph node

Primary Tumor Site Discrepancy	Not Stated on path	

Source: NCI Genomic Data Commons file 343d9eb4-6a56-4a5e-ab86-56ae171adcd7 (TCGA-FS-A1Z4.D364F280-C02C-4D3F-AE1A-E6439EFFB6D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).